Somatic mutation profile of tumor specimen TCGA-MM-A84U-01A (aliquot TCGA-MM-A84U-01A-11D-A36X-10) from TCGA case TCGA-MM-A84U, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 58.5 years (21,375 days).
Specimen TCGA-MM-A84U-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5836fae8-80cc-4494-b7fa-e6ab3d8d414f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-MM-A84U-10A (Blood Derived Normal), aliquot TCGA-MM-A84U-10A-01D-A370-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/09c137f5-fc84-42f6-a6ae-a5237f8770d4

The open-access MAF lists 77 somatic variants for this specimen: 65 protein-altering or splice-affecting, 10 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 49, Silent 10, Frame Shift Del 6, Nonsense Mutation 3, In Frame Del 3, Splice Site 2, 5'Flank 1, Splice Region 1, RNA 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA8 | c.2914G>A p.E972K | Missense Mutation (SNP) | VAF 7/84 reads (8%) | SIFT tolerated (0.72); PolyPhen benign (0.027); catalogued as COSV52214036, COSV99285400; called by muse, mutect2
- ACTL6A | c.971G>C p.G324A | Missense Mutation (SNP) | VAF 19/147 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.569); catalogued as COSV101199656; called by muse, mutect2, varscan2
- ADAMTS3 | c.682G>A p.D228N | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.045); catalogued as rs1343806941, COSV99710717; called by muse, mutect2, varscan2
- ADNP | c.1867C>A p.L623I | Missense Mutation (SNP) | VAF 46/141 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.156); catalogued as COSV100823693, COSV62424619; called by muse, mutect2, varscan2
- AL662899.2 | c.139C>T p.R47* | Nonsense Mutation (SNP) | VAF 13/64 reads (20%) | catalogued as rs1085307703, COSV100788996; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- API5 | c.1092A>C p.K364N | Missense Mutation (SNP) | VAF 37/152 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0.388); catalogued as COSV101124520; called by muse, mutect2, varscan2
- ATP4A | c.2073G>T p.E691D | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.68); PolyPhen benign (0.019); catalogued as COSV99382410; called by muse, mutect2, varscan2
- BRD8 | c.43C>A p.P15T | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99136792; called by muse, mutect2, varscan2
- C1S | c.7T>A p.C3S | Missense Mutation (SNP) | VAF 26/149 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.028); catalogued as COSV100196496; called by muse, mutect2, varscan2
- CACNB4 | c.365C>T p.A122V | Missense Mutation (SNP) | VAF 6/128 reads (5%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.98); catalogued as COSV99137995; called by muse, mutect2
- CAPN3 | c.2387T>A p.F796Y | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.488); catalogued as COSV99782431; called by muse, mutect2, varscan2
- CCDC191 | c.1447C>T p.P483S | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as rs267599552, COSV99878101; called by muse, mutect2, varscan2
- CENPT | c.720C>A p.D240E | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.084); catalogued as COSV99534980; called by muse, mutect2, varscan2
- CETP | c.309T>G p.I103M | Missense Mutation (SNP) | VAF 27/112 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99569975; called by muse, mutect2, varscan2
- CHD4 | c.3460A>G p.K1154E (on ENST00000357008 / NM_001363606.2; = p.K1167E on NM_001273.5) | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.124); catalogued as COSV100537714; called by muse, mutect2, varscan2
- CHRDL1 | c.496G>C p.D166H (on ENST00000372045; = p.D172H on NM_145234.4) | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.677); catalogued as COSV54327084, COSV99487934; called by muse, mutect2, varscan2
- CNKSR3 | c.920T>C p.L307P | Missense Mutation (SNP) | VAF 30/124 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV101401336; called by muse, mutect2, varscan2
- CXCL1 | c.202C>T p.H68Y | Missense Mutation (SNP) | VAF 19/133 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV101203922; called by muse, mutect2, varscan2
- EHBP1 | c.2899A>T p.S967C | Missense Mutation (SNP) | VAF 55/237 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.599); catalogued as COSV99860546; called by muse, mutect2, varscan2
- ENPP1 | c.1068G>T p.W356C | Missense Mutation (SNP) | VAF 40/170 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100719481; called by muse, mutect2, varscan2
- FBXL13 | c.346C>T p.Q116* | Nonsense Mutation (SNP) | VAF 40/163 reads (25%) | catalogued as rs773449929, COSV100501408; called by muse, mutect2, varscan2
- FGD1 | c.1960C>G p.L654V | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT tolerated (0.41); PolyPhen benign (0.017); catalogued as COSV100910994; called by muse, mutect2, varscan2
- GJB1 | c.155T>C p.I52T | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT tolerated (0.66); PolyPhen benign (0.015); catalogued as CD095484, COSV100661254; called by muse, mutect2, varscan2
- HPN | c.718C>G p.H240D | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99385005; called by muse, mutect2, varscan2
- IFT80 | c.1438G>A p.A480T | Missense Mutation (SNP) | VAF 79/374 reads (21%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.727); catalogued as COSV100424609; called by muse, mutect2, varscan2
- ITGA1 | c.652G>A p.V218M | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as rs1003303207, COSV99251050; called by muse, mutect2, varscan2
- ITGA5 | c.2484T>A p.H828Q | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.194); catalogued as COSV99516550; called by muse, mutect2
- KIF26A | c.964C>T p.P322S | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.35); PolyPhen benign (0.017); catalogued as COSV100181018; called by muse, mutect2, varscan2
- KRTAP5-1 | c.562G>A p.G188S | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.099); catalogued as rs145180041; called by muse, varscan2
- LMAN1 | c.1527C>G p.F509L | Missense Mutation (SNP) | VAF 28/227 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.022); catalogued as COSV99195327; called by muse, mutect2, varscan2
- LMNA | c.1813G>A p.A605T | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.025); catalogued as COSV100738595; called by muse, mutect2, varscan2
- MORC4 | c.2321G>A p.R774K | Missense Mutation (SNP) | VAF 59/219 reads (27%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.952); catalogued as COSV99717045; called by muse, mutect2, varscan2
- MTOR | c.2263C>T p.R755C | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs879251235, COSV63874415; called by muse, mutect2, varscan2
- NDST4 | c.440G>A p.R147Q | Missense Mutation (SNP) | VAF 39/137 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.485); catalogued as rs1327129332, COSV52109545; called by muse, mutect2, varscan2
- NES | c.352G>A p.A118T | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.675); catalogued as COSV63962047; called by muse, mutect2, varscan2
- OPRD1 | c.841G>A p.V281I | Missense Mutation (SNP) | VAF 26/99 reads (26%) | SIFT tolerated (0.44); PolyPhen benign (0.028); catalogued as rs1160699595, COSV99330184; called by muse, mutect2, varscan2
- PCDHGC3 | c.902C>G p.T301S | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.28); catalogued as COSV99339318; called by muse, mutect2, varscan2
- RBFOX1 | c.678C>T p.G226= | Splice Region (SNP) | VAF 20/96 reads (21%) | catalogued as COSV100300665; called by muse, varscan2
- RHOBTB3 | c.376G>A p.V126I | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.01); catalogued as COSV101183162; called by muse, mutect2, varscan2
- ROR2 | c.967G>T p.D323Y | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV100995689; called by muse, mutect2, varscan2
- RYR2 | c.892C>T p.R298C | Missense Mutation (SNP) | VAF 64/228 reads (28%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.939); catalogued as rs551099887, COSV63685496; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- SLC17A5 | c.329G>T p.W110L | Missense Mutation (SNP) | VAF 31/158 reads (20%) | SIFT tolerated (0.64); PolyPhen benign (0.055); catalogued as COSV100867032; called by muse, mutect2, varscan2
- SLC35B1 | c.208G>A p.E70K (on ENST00000649906; = p.E33K on NM_005827.4) | Missense Mutation (SNP) | VAF 39/144 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99539415; called by muse, mutect2, varscan2
- SMARCC2 | c.958C>T p.P320S | Missense Mutation (SNP) | VAF 70/224 reads (31%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.968); catalogued as COSV99911121; called by muse, mutect2, varscan2
- SPG21 | c.64-1G>C p.X22_splice | Splice Site (SNP) | VAF 15/46 reads (33%) | catalogued as COSV99200185; called by muse, mutect2, varscan2
- SRRM2 | c.320G>C p.G107A | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as COSV100070572; called by muse, mutect2, varscan2
- SV2C | c.2089A>C p.K697Q | Missense Mutation (SNP) | VAF 41/165 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100455972; called by muse, mutect2, varscan2
- TEX55 | c.1605G>T p.Q535H | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55210839; called by mutect2, varscan2
- TTC16 | c.1610C>T p.A537V | Missense Mutation (SNP) | VAF 7/78 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.131); catalogued as COSV100262845; called by muse, mutect2, varscan2
- TTN | c.91376T>C p.V30459A (on ENST00000591111; = p.V23035A on NM_003319.4) | Missense Mutation (SNP) | VAF 38/143 reads (27%) | PolyPhen probably damaging (0.99); catalogued as rs794729541, COSV100604566; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UBN2 | c.492C>G p.D164E | Missense Mutation (SNP) | VAF 40/162 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as COSV99943824; called by muse, mutect2, varscan2
- UTP3 | c.1369G>A p.E457K | Missense Mutation (SNP) | VAF 7/178 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99636965; called by muse, mutect2
- WRAP73 | c.87C>G p.Y29* | Nonsense Mutation (SNP) | VAF 7/49 reads (14%) | catalogued as COSV99573237; called by muse, mutect2, varscan2
- ZNF761 | c.1176T>A p.S392R | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.42); PolyPhen benign (0.116); catalogued as COSV100483329; called by muse, varscan2
- B9D2 | c.430del p.A144Pfs*68 | Frame Shift Del (DEL) | VAF 15/66 reads (23%) | called by mutect2, pindel, varscan2
- FAF1 | c.1433_1435del p.M478del | In Frame Del (DEL) | VAF 29/141 reads (21%) | called by pindel, varscan2
- FBN3 | c.7235_7236del p.V2412Afs*75 | Frame Shift Del (DEL) | VAF 17/99 reads (17%) | called by mutect2, pindel, varscan2
- INPP4B | c.2415_2417del p.L806del | In Frame Del (DEL) | VAF 19/89 reads (21%) | called by mutect2, pindel, varscan2
- KIF13B | c.167_178del p.F56_H60delinsY | In Frame Del (DEL) | VAF 16/66 reads (24%) | called by mutect2, pindel, varscan2
- LAD1 | c.406_416delinsT p.K136* | Frame Shift Del (DEL) | VAF 35/146 reads (24%) | called by pindel, varscan2*
- NALCN | c.783_799+2del p.X261_splice | Splice Site (DEL) | VAF 12/92 reads (13%) | called by mutect2, pindel
- RAD50 | c.1593_1596del p.H531Qfs*10 | Frame Shift Del (DEL) | VAF 38/164 reads (23%) | called by mutect2, pindel, varscan2
- TCF20 | c.2635del p.D879Tfs*10 | Frame Shift Del (DEL) | VAF 32/121 reads (26%) | called by mutect2, pindel, varscan2
- TPX2 | c.1974del p.E658Dfs*24 | Frame Shift Del (DEL) | VAF 30/111 reads (27%) | called by mutect2, pindel, varscan2
- ZNF761 | c.1173dup p.S392* | Frame Shift Ins (INS) | VAF 6/49 reads (12%) | called by pindel, varscan2
- ASIC3 | c.1170G>A p.A390= | Silent (SNP) | VAF 5/31 reads (16%) | catalogued as rs1391654001, COSV99876794; called by muse, mutect2, varscan2
- ATP1A3 | c.3000C>A p.L1000= (on ENST00000545399 / NM_001256214.2; = p.L987= on NM_152296.5) | Silent (SNP) | VAF 11/38 reads (29%) | catalogued as COSV100132168; called by muse, mutect2, varscan2
- DNAI2 | c.1080C>T p.F360= | Silent (SNP) | VAF 19/78 reads (24%) | catalogued as COSV100209664; called by muse, mutect2
- HAGH | c.849C>T p.H283= | Silent (SNP) | VAF 14/47 reads (30%) | catalogued as rs771431266, COSV68401220; called by muse, mutect2, varscan2
- MORC3 | c.1170T>C p.N390= | Silent (SNP) | VAF 63/256 reads (25%) | catalogued as COSV101247726; called by muse, mutect2, varscan2
- NTNG1 | c.1584C>T p.T528= (on ENST00000370068 / NM_001113226.3; = p.T427= on NM_014917.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 6/45 reads (13%) | catalogued as rs1199057745, COSV100903476; called by muse, mutect2, varscan2
- OVOL1 | c.564T>C p.S188= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as COSV100256799; called by muse, mutect2, varscan2
- PSMD11 | c.51C>T p.S17= | Silent (SNP) | VAF 10/145 reads (7%) | catalogued as COSV99912403; called by muse, mutect2
- SALL4 | c.2697G>T p.V899= | Silent (SNP) | VAF 14/53 reads (26%) | catalogued as COSV99409390; called by muse, mutect2, varscan2
- TLN2 | c.5307T>C p.T1769= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as COSV100168655; called by muse, mutect2, varscan2
- AFDN | chr6:167825888 A>T | 5'Flank (SNP) | VAF 13/49 reads (27%) | called by muse, mutect2, varscan2
- ZNF271P | n.1955C>G | RNA (SNP) | VAF 26/95 reads (27%) | called by muse, mutect2, varscan2
